Gene-level copy-number profile of tumor specimen TCGA-AM-5820-01A from TCGA case TCGA-AM-5820, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Age at diagnosis: 60.0 years (21,902 days).
Specimen TCGA-AM-5820-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.fe9f30de-ba46-45db-90d3-0e283a909aa2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AM-5820-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/33d91e73-4851-4db4-acb2-48fe24abcb8d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 8,389; copy number 2: 47,669; copy number 3: 3,710.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AM-5820-01A-01D-1649-01): tumor purity 0.77, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:132,296,055–132,539,336, 4 genes (within-gene range 0–1): MOXD1, STX7, RPL21P66, TAAR9.
- chr10:87,500,337–88,851,844, 30 genes (within-gene range 0–1): AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22.
- chr15:66,860,303–67,255,195, 8 genes (within-gene range 0–2): AC110048.2, AC093334.1, LINC02206, AC087482.1, HMGN2P47, SMAD3, AC012568.1, AAGAB.
- chr16:17,405,678–18,151,595, 8 genes (within-gene range 0–1): AC009152.6, AC009152.1, AC009152.3, AC109495.1, AC025277.1, RPL7P47, AC010601.1, AC010601.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,388. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
